Somatic mutation profile of tumor specimen TCGA-F4-6805-01A (aliquot TCGA-F4-6805-01A-11D-1835-10) from TCGA case TCGA-F4-6805, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 58.2 years (21,241 days).
Specimen TCGA-F4-6805-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b295002-58cc-43f0-9b5b-b9ebfd0fbf99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F4-6805-10A (Blood Derived Normal), aliquot TCGA-F4-6805-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea570e2b-ef50-46ca-9d9e-674557fb93b7

The open-access MAF lists 76 somatic variants for this specimen: 56 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 17, Nonsense Mutation 4, RNA 2, Frame Shift Del 2, Splice Region 1, In Frame Del 1, Intron 1, Splice Site 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>C p.Q61P | Missense Mutation (SNP) | VAF 22/48 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PIK3CA | c.3019G>C p.G1007R | Missense Mutation (SNP) | VAF 24/120 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.797); catalogued as COSV55882140; called by muse, mutect2, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 16/38 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADARB1 | c.2032C>T p.R678C (on ENST00000360697 / NM_001346687.2; = p.R638C on NM_001112.4) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs1298111041, COSV62348177; called by muse, mutect2
- ATRX | c.838T>A p.C280S | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64875399, COSV64877084; called by muse, mutect2, varscan2
- BCKDHB | c.199del p.Q67Kfs*5 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as COSV57512301; called by mutect2, pindel, varscan2
- BCOR | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs865796679, COSV60705743; called by muse, mutect2, varscan2
- BNC1 | c.2045G>A p.G682E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs765009276, COSV61757209; called by muse, mutect2, varscan2
- C5orf22 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV57598181; called by muse, mutect2, varscan2
- CCL3L3 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 83/634 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs1166624794; called by muse, varscan2
- CENPV | c.494A>G p.H165R | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV55333196; called by muse, mutect2, varscan2
- CPT1A | c.1306A>G p.M436V | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV55755299; called by muse, mutect2, varscan2
- DPEP2 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs753813676, COSV52054388; called by muse, mutect2, varscan2
- DYSF | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs184771575, COSV50303935; called by muse, mutect2, varscan2
- FAM161B | c.1298C>T p.P433L (on ENST00000651776; = p.P370L on NM_152445.3) | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV54101978; called by muse, mutect2, varscan2
- FBXW12 | c.1220A>G p.E407G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99601414; called by muse, mutect2, varscan2
- FGG | c.123C>T p.F41= | Splice Region (SNP) | VAF 18/99 reads (18%) | catalogued as rs141554929; called by muse, mutect2, varscan2
- FLT4 | c.2404_2406del p.R802del | In Frame Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs776555888; called by pindel, varscan2
- GLT1D1 | c.673C>T p.R225* (on ENST00000442111 / NM_001366889.1; = p.R145* on NM_144669.3) | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as rs1295924730, COSV55880944; called by muse, mutect2, varscan2
- GPR50 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as COSV99505563; called by muse, mutect2
- IL17RC | c.2056T>A p.C686S (on ENST00000295981 / NM_153461.4; = p.C600S on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55973006; called by muse, mutect2
- KLHL4 | c.1987G>C p.V663L | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV64141657; called by muse, mutect2, varscan2
- LRRC40 | c.1453A>T p.N485Y | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV63942147; called by muse, mutect2, varscan2
- MAPK10 | c.489C>A p.C163* (on ENST00000359221 / NM_001351625.2; = p.C201* on NM_002753.5) | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100173645; called by muse, mutect2, varscan2
- MUC16 | c.40321A>C p.T13441P | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as COSV101109560; called by muse, mutect2, varscan2
- NEDD9 | c.1955A>G p.N652S | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV101060747; called by mutect2, varscan2
- NEXN | c.1933T>C p.F645L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1278330309, COSV53929980; called by muse, mutect2, varscan2
- NHS | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs758435083, COSV66271082; called by muse, mutect2, varscan2
- NLK | c.847T>G p.F283V | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63490580; called by muse, mutect2, varscan2
- NTSR1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764154462, COSV65138432; called by muse, mutect2, varscan2
- NUP43 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as rs368190862; called by muse, mutect2, varscan2
- OOEP | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as COSV64859171; called by muse, mutect2, varscan2
- OR2T3 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100613032; called by muse, mutect2, varscan2
- PHACTR3 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs762960052, COSV63025573; called by mutect2, varscan2
- PIF1 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as rs773939962, COSV51421641; called by muse, mutect2, varscan2
- PJA1 | c.1190C>T p.P397L (on ENST00000361478 / NM_145119.4; = p.P209L on NM_022368.5) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs180767696, COSV64053758; called by muse, mutect2, varscan2
- PLEKHG1 | c.916A>G p.I306V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.443); catalogued as COSV100651438; called by mutect2, varscan2
- RABGGTB | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99590488; called by mutect2, varscan2
- SCN7A | c.882C>G p.N294K | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs762095367, COSV69270947; called by muse, mutect2, varscan2
- SMARCD1 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.009); catalogued as COSV99947884; called by muse, mutect2
- SRGAP2 | c.2344G>A p.V782M (on ENST00000624873 / NM_001170637.4; = p.V783M on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs769054196, COSV99832322; called by muse, mutect2, varscan2
- SVEP1 | c.9655T>C p.S3219P | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV99928156; called by muse, mutect2, varscan2
- TMEM132D | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs751041490, COSV70594645; called by muse, mutect2, varscan2
- TUBA3E | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs1376385373, COSV56058819; called by muse, mutect2, varscan2
- VPS13B | c.4220A>G p.K1407R | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV62139590; called by muse, mutect2, varscan2
- VPS26C | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs746453273, COSV55706019; called by muse, mutect2, varscan2
- VPS50 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as rs371166383, COSV58505986; called by muse, mutect2, varscan2
- WDR19 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV56464555; called by muse, mutect2, varscan2
- ZFHX4 | c.8783G>T p.G2928V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1205670770, COSV50647411; called by muse, mutect2, varscan2
- ZNF385D | c.877G>T p.D293Y | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55776764, COSV99873058; called by muse, mutect2, varscan2
- ZNF493 | c.1453T>A p.S485T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.457); catalogued as COSV62749881; called by muse, mutect2, varscan2
- ZNF497 | c.1453C>A p.L485I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54050616; called by muse, mutect2, varscan2
- ME1 | c.908_912+7del p.X303_splice | Splice Site (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- OCLN | c.39del p.R13Sfs*52 | Frame Shift Del (DEL) | VAF 25/122 reads (20%) | called by mutect2, pindel, varscan2
- SOX9 | c.818_819dup p.D274Wfs*6 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | called by mutect2, pindel
- AKAP12 | c.3732G>A p.E1244= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV53573863; called by muse, mutect2, varscan2
- ARHGAP33 | c.147C>T p.C49= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs754749619, COSV99137488; called by mutect2, varscan2
- BBS9 | c.324C>G p.V108= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV54165587; called by muse, mutect2, varscan2
- COL7A1 | c.1428G>A p.P476= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs138330564; called by muse, mutect2, varscan2
- FAM135B | c.2871C>T p.S957= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as rs757748275, COSV52720425; called by muse, mutect2, varscan2
- FOXG1 | c.654C>T p.Y218= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100486507; called by mutect2, varscan2
- GFM1 | c.168T>C p.D56= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs768555221, COSV99962646; called by muse, mutect2, varscan2
- KLK6 | c.75C>T p.G25= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs1401187950, COSV59565425; called by muse, mutect2, varscan2
- MAGEB3 | c.117C>A p.S39= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV64396756; called by muse, mutect2, varscan2
- MASP2 | c.369C>T p.N123= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs764259519, COSV68896118; called by muse, mutect2, varscan2
- NTNG1 | c.24G>A p.S8= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs557686809, COSV53969144; called by muse, mutect2, varscan2
- OR4N5 | c.561G>T p.L187= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV61320440, COSV61321469; called by muse, mutect2, varscan2
- OR51B6 | c.741G>T p.L247= | Silent (SNP) | VAF 32/158 reads (20%) | catalogued as COSV66512858; called by muse, mutect2, varscan2
- SERPINA9 | c.1209C>T p.D403= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as rs755418651, COSV54075934; called by muse, mutect2, varscan2
- SMC1A | c.1375C>T p.L459= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100446977; called by muse, varscan2
- SMPDL3A | c.333C>T p.S111= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs1317316135, COSV100868658; called by muse, mutect2, varscan2
- WDR49 | c.576C>T p.N192= (on ENST00000308378 / NM_001366158.1; = p.N533= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs372277287; called by muse, mutect2, varscan2
- NBPF25P | n.1038C>G | RNA (SNP) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- PHACTR1 | c.251-119669G>A | Intron (SNP) | VAF 14/55 reads (25%) | catalogued as rs370177537; called by muse, mutect2, varscan2
- SSPOP | n.7166G>A | RNA (SNP) | VAF 22/106 reads (21%) | catalogued as rs1262647935, COSV50487749; called by muse, mutect2, varscan2
